CCDI case PBCEVY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/b33717f6-7d69-41b4-a892-7363f2d5b012

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Granulosa cell tumor, juvenile: ICD-O-3 morphology code: 8622/1; Tissue or organ of origin: Ovary; Age at diagnosis: 0.7 years (266 days).

Biospecimens (3 samples)
- Sample 0DQFIX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DQFJ1, 0DQFJ5 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
